Somatic mutation profile of tumor specimen ALCH-B1U1-TTP1-A (aliquot ALCH-B1U1-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1U1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.7 years (24,013 days).
Specimen ALCH-B1U1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 289584f0-0a39-427b-9546-5978bff2174f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1U1-NB1-A (Blood Derived Normal), aliquot ALCH-B1U1-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69cd7f55-0929-4791-8453-e94c7cd5c89c

The open-access MAF lists 483 somatic variants for this specimen: 345 protein-altering or splice-affecting, 82 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 285, Silent 82, Nonsense Mutation 31, Intron 21, RNA 14, Frame Shift Del 10, Splice Site 9, Splice Region 7, 5'UTR 7, 3'UTR 7, 5'Flank 5, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUTYH | c.1177+1G>T p.X393_splice | Splice Site (SNP) | VAF 37/289 reads (13%) | catalogued as rs587781337; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 57/488 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.262G>T p.D88Y | Missense Mutation (SNP) | VAF 31/188 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as rs750983163; called by muse, mutect2, varscan2
- ADAMTS10 | c.3064G>A p.G1022R | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as rs1234657915; called by muse, mutect2
- ADAMTS20 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101166419, COSV101166427; called by muse, mutect2
- ADGRG4 | c.4512G>T p.M1504I | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV99794011; called by muse, mutect2, varscan2
- ANKFN1 | c.1065G>T p.W355C | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59444137; called by muse, mutect2, varscan2
- ANKRD35 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100841857; called by muse, mutect2, varscan2
- APOB | c.1054G>C p.V352L | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51939700; called by muse, mutect2, varscan2
- ASL | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.872); catalogued as rs749233780; called by muse, mutect2
- ASPM | c.5770G>A p.A1924T | Missense Mutation (SNP) | VAF 48/599 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.41); catalogued as rs780503880; called by muse, mutect2
- ATAD3B | c.701A>G p.K234R (on ENST00000308647; = p.K340R on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs370502580; called by muse, mutect2, varscan2
- ATAD5 | c.2770A>T p.K924* | Nonsense Mutation (SNP) | VAF 19/217 reads (9%) | catalogued as COSV58974587; called by muse, mutect2
- C16orf90 | c.361C>A p.P121T (on ENST00000399645 / NM_001353385.2; = p.P112T on NM_001080524.2) | Missense Mutation (SNP) | VAF 39/383 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.046); catalogued as COSV68714565; called by muse, mutect2, varscan2
- C4orf54 | c.4488del p.N1497Tfs*13 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | catalogued as rs1249107798; called by mutect2, pindel, varscan2
- CD40 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs764257725, COSV64847521; called by muse, mutect2, varscan2
- CDH4 | c.1907C>A p.A636D | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as COSV64653762; called by muse, mutect2
- CFAP53 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as rs766960984, COSV68352564; ClinVar: uncertain significance; called by muse, mutect2
- CFAP61 | c.1254C>A p.N418K | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.295); catalogued as rs759441638; called by muse, mutect2
- CHRNA4 | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV64721189; called by muse, mutect2, varscan2
- COL9A2 | c.186G>C p.P62= | Splice Region (SNP) | VAF 56/535 reads (10%) | catalogued as CS022489, CS991357; called by muse, mutect2, varscan2
- CPB1 | c.559C>A p.Q187K | Missense Mutation (SNP) | VAF 46/231 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51577177; called by muse, mutect2, varscan2
- CYP4F2 | c.1507G>T p.E503* | Nonsense Mutation (SNP) | VAF 12/240 reads (5%) | catalogued as rs1307479646; called by muse, mutect2
- DAP3 | c.241del p.H81Mfs*8 | Frame Shift Del (DEL) | VAF 24/235 reads (10%) | catalogued as COSV58018995; called by mutect2, pindel
- DYSF | c.3294G>T p.M1098I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV50491773; called by muse, mutect2, varscan2
- EBLN2 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV55597251; called by muse, mutect2
- EIF2A | c.1186A>G p.I396V | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1019440553; called by muse, mutect2
- EPPK1 | c.6319C>G p.Q2107E | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.025); catalogued as rs782374797; called by muse, mutect2, varscan2
- FAT2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.517); catalogued as COSV55825486; called by muse, mutect2, varscan2
- FAT3 | c.4211G>T p.S1404I | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV53186297; called by muse, varscan2
- FBXL13 | c.865C>T p.R289* | Nonsense Mutation (SNP) | VAF 74/317 reads (23%) | catalogued as rs768134477, COSV99978704; called by muse, mutect2, varscan2
- FLG2 | c.3433G>T p.E1145* | Nonsense Mutation (SNP) | VAF 16/182 reads (9%) | catalogued as COSV66173317; called by muse, mutect2
- FLNC | c.5142C>A p.Y1714* | Nonsense Mutation (SNP) | VAF 52/269 reads (19%) | catalogued as COSV57957292, COSV57957544; called by muse, mutect2, varscan2
- FLRT3 | c.983A>G p.N328S | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.349); catalogued as rs779346527, COSV53942836; called by muse, mutect2, varscan2
- FOXG1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as rs1235342890; called by muse, mutect2, varscan2
- GAB4 | c.1312A>T p.R438* | Nonsense Mutation (SNP) | VAF 29/264 reads (11%) | catalogued as COSV101272065, COSV101272066; called by muse, mutect2, varscan2
- GABRQ | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs781935399, COSV64781836; called by muse, mutect2, varscan2
- GIMAP1 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs750672448; called by muse, mutect2, varscan2
- GLRA4 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 27/203 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65455214; called by muse, mutect2, varscan2
- GNL2 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs368568971; called by muse, mutect2
- GRIA2 | c.968G>T p.R323L | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs142538282, COSV52402874; called by muse, mutect2, varscan2
- GTF2H2 | c.468A>G p.L156= | Splice Region (SNP) | VAF 24/228 reads (11%) | catalogued as rs1307441036; called by muse, mutect2, varscan2
- HTR4 | c.901G>T p.G301C | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58792288; called by muse, mutect2
- IGHV3-43 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 49/513 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as rs756956812; called by muse, mutect2
- IGKV3-20 | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 70/814 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1385277339; called by muse, mutect2
- INPP4B | c.1234G>A p.E412K | Missense Mutation (SNP) | VAF 32/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53728153; called by muse, varscan2
- ITGA2B | c.1883G>C p.R628P | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52232893; called by muse, mutect2, varscan2
- KANSL1 | c.2707G>A p.E903K (on ENST00000574590 / NM_001193465.2; = p.E904K on NM_015443.4) | Missense Mutation (SNP) | VAF 23/407 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52265208; called by muse, mutect2
- KCNH5 | c.896C>G p.S299C | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100527908; called by muse, mutect2, varscan2
- KRTAP24-1 | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 36/576 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as COSV61089546; called by muse, mutect2
- KYNU | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs768919861; called by muse, mutect2, varscan2
- LCN8 | c.161G>T p.R54L (on ENST00000612714 / NM_001345934.1; = p.R31L on NM_178469.3) | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100293219; called by muse, mutect2
- LIFR | c.2258G>A p.R753K | Missense Mutation (SNP) | VAF 11/261 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); catalogued as rs1561135707, COSV99665488; called by muse, mutect2
- LRP1B | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1037245912; called by muse, mutect2, varscan2
- MARCO | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.247); catalogued as rs1222641496, COSV59052476; called by muse, mutect2
- MGAM2 | c.2441T>A p.V814E | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101522927; called by muse, mutect2, varscan2
- MRPS12 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs772487012, COSV55498188; called by mutect2, varscan2
- MUC16 | c.7673C>T p.S2558L | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as COSV101201789; called by muse, mutect2, varscan2
- NR0B1 | c.371G>T p.R124L | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV66763798; called by muse, mutect2, varscan2
- NTRK3 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 20/278 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs774739739, COSV100446846; called by muse, mutect2
- OR10J3 | c.442G>C p.G148R | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59955212, COSV59955621; called by muse, mutect2
- OR2AP1 | c.772A>G p.I258V | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.009); catalogued as rs557910812; called by muse, mutect2, varscan2
- OR2G6 | c.219T>A p.F73L | Missense Mutation (SNP) | VAF 36/502 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV58575694; called by muse, mutect2
- OR5T3 | c.574G>T p.D192Y | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758340845; called by muse, mutect2
- OR8J1 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.076); catalogued as rs771184196, COSV100274944, COSV57317616; called by muse, mutect2
- OTOGL | c.5763G>T p.M1921I (on ENST00000547103; = p.M1912I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100087125, COSV54025444; called by muse, varscan2
- OTOP1 | c.1218G>T p.W406C | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588017; called by muse, mutect2
- PAPPA | c.3480G>T p.Q1160H | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV60282159; called by muse, mutect2
- PAPSS1 | c.822G>T p.W274C | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54492826; called by muse, mutect2
- PCDH15 | c.4072G>C p.E1358Q | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs766259569, COSV100219399, COSV57410863; called by muse, mutect2
- PCDH17 | c.1093G>T p.A365S | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.59); catalogued as rs745877167, COSV100931636; called by muse, mutect2, varscan2
- PEX6 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV99769935; called by muse, mutect2, varscan2
- PKD2L1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 29/480 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765174470, COSV58398311; called by muse, mutect2
- PKHD1L1 | c.8242C>G p.R2748G | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV101006603; called by muse, mutect2
- PLAGL2 | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs757572858; called by muse, mutect2, varscan2
- POLE | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773204331, COSV57689277; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POM121 | c.2894G>C p.G965A (on ENST00000434423; = p.G700A on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs782426722, COSV57513382; called by muse, mutect2
- PSG1 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54944755; called by muse, mutect2, varscan2
- PTPRD | c.2750T>A p.V917E | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs995319192; called by muse, mutect2
- RIMS1 | c.2542G>C p.E848Q | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53436563; called by muse, mutect2, varscan2
- RPE65 | c.354-1G>T p.X118_splice | Splice Site (SNP) | VAF 29/232 reads (13%) | catalogued as COSV99254075; called by muse, mutect2, varscan2
- SATB2 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.165); catalogued as rs1367686940; called by muse, mutect2, varscan2
- SBSN | c.1661C>A p.S554Y (on ENST00000452271 / NM_001166034.2; = p.S211Y on NM_198538.4) | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV101510080; called by muse, mutect2, varscan2
- SETBP1 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 36/709 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as rs781159539; ClinVar: uncertain significance; called by muse, mutect2
- SLC26A2 | c.873A>G p.I291M | Missense Mutation (SNP) | VAF 28/305 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs1329630708; called by muse, mutect2
- SLC34A2 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1327576349; called by muse, mutect2, varscan2
- ST6GAL2 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | PolyPhen possibly damaging (0.786); catalogued as COSV64527778, COSV64528359; called by muse, mutect2, varscan2
- SULT1A2 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs749565589; called by muse, mutect2
- SYCP1 | c.1530G>T p.K510N | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as COSV65698901; called by muse, mutect2, varscan2
- TAF1L | c.2618del p.R873Pfs*38 | Frame Shift Del (DEL) | VAF 40/342 reads (12%) | catalogued as COSV54270781; called by mutect2, pindel, varscan2
- TBXT | c.1252G>T p.A418S | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99752830; called by muse, mutect2, varscan2
- TEX13C | c.708G>T p.M236I | Missense Mutation (SNP) | VAF 28/149 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs933415062; called by muse, mutect2, varscan2
- TMEFF1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58496121; called by muse, mutect2
- TMEM115 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV51704444; called by muse, mutect2, varscan2
- TPO | c.2427C>G p.H809Q | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV61099834; called by muse, mutect2
- TRAV18 | c.235G>T p.G79C | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749337587; called by muse, mutect2
- TRIM77 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68067140; called by muse, mutect2
- TRIM9 | c.1370G>A p.S457N | Missense Mutation (SNP) | VAF 44/482 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100031473; called by muse, mutect2
- UBE2D1 | c.436G>T p.A146S | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV64219009; called by muse, mutect2
- UGT1A10 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as rs748336675; called by muse, mutect2, varscan2
- UGT2B15 | c.1412A>T p.H471L | Missense Mutation (SNP) | VAF 32/325 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100592244; called by muse, varscan2
- VWA5A | c.2066A>G p.N689S | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs1038226410; called by muse, mutect2, varscan2
- WDR17 | c.2533-1G>T p.X845_splice | Splice Site (SNP) | VAF 36/404 reads (9%) | catalogued as COSV54572163; called by muse, mutect2
- ZC4H2 | c.399-5C>A | Splice Region (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100564920; called by muse, mutect2, varscan2
- ZNF189 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.107); catalogued as rs746988808, COSV52275789; called by muse, mutect2, varscan2
- ZNF285 | c.602A>G p.E201G | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs763126590; called by muse, mutect2, varscan2
- ZP4 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV63910880; called by muse, mutect2
- ABCD1 | c.1025C>A p.S342* | Nonsense Mutation (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- ABLIM3 | c.853G>T p.G285* | Nonsense Mutation (SNP) | VAF 25/387 reads (6%) | called by muse, mutect2
- ABLIM3 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- AC011005.1 | c.1057C>A p.P353T | Missense Mutation (SNP) | VAF 36/345 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- AC099489.1 | c.3905T>A p.V1302E | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2, varscan2
- ACKR1 | c.273G>T p.Q91H | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.88); called by muse, mutect2
- ADAM19 | c.1547G>T p.G516V | Missense Mutation (SNP) | VAF 24/487 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADCYAP1R1 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- ADGRF4 | c.323T>A p.L108H | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); called by muse, mutect2
- ADGRG4 | c.7495G>C p.D2499H | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ADGRL4 | c.1587G>T p.L529F | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.979); called by muse, mutect2
- AGXT | c.448C>A p.L150M | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.122); called by muse, mutect2
- AHNAK2 | c.16424A>C p.Q5475P | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2
- AKNA | c.2749A>T p.M917L | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- AKR1D1 | c.532C>A p.L178I | Missense Mutation (SNP) | VAF 49/462 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- AMPH | c.1684G>A p.G562S | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2
- ANK2 | c.4318C>A p.L1440M | Missense Mutation (SNP) | VAF 48/424 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARHGAP4 | c.1630G>T p.V544L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ASTN2 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- ATF7IP | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | called by muse, mutect2, varscan2
- BCAS1 | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- C1QC | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2
- C4orf54 | c.41C>G p.T14R | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- C8orf34 | c.641G>T p.W214L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CA9 | c.178C>A p.L60M | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.523); called by mutect2, varscan2
- CACNA1I | c.4692G>T p.M1564I | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CADPS | c.2866G>T p.D956Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- CALHM2 | c.480C>A p.F160L | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2
- CARD10 | c.2365C>A p.R789S | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CARD11 | c.729T>A p.C243* | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- CARMIL1 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CASQ1 | c.982del p.L328Cfs*19 | Frame Shift Del (DEL) | VAF 20/199 reads (10%) | called by mutect2, pindel
- CCDC112 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); called by muse, mutect2
- CD177 | c.1116C>A p.C372* | Nonsense Mutation (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- CDH8 | c.1771A>T p.T591S | Missense Mutation (SNP) | VAF 74/922 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CEP290 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.603); called by muse, mutect2
- CEP295 | c.3608G>T p.G1203V | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- CFAP47 | c.5452C>A p.P1818T | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- CHD1L | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2
- CHD1L | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- CHD7 | c.6839G>C p.R2280T | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.121); called by muse, mutect2
- CHSY3 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 17/182 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2
- CLEC14A | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 30/252 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CLSPN | c.3039T>A p.D1013E | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN1 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COG7 | c.319G>T p.V107L | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- COL27A1 | c.4682G>T p.R1561L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- COL4A2 | c.617A>G p.Q206R | Missense Mutation (SNP) | VAF 70/464 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CPS1 | c.3044G>A p.C1015Y | Missense Mutation (SNP) | VAF 35/256 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CPZ | c.399C>A p.F133L (on ENST00000360986 / NM_001014447.3; = p.F122L on NM_003652.3) | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.236); called by mutect2, varscan2
- CREB3L4 | c.979T>A p.Y327N | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.365); called by muse, mutect2
- CSMD1 | c.3323G>T p.S1108I (on ENST00000520002; = p.S1107I on NM_033225.6) | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CSMD3 | c.8866G>T p.G2956C (on ENST00000297405 / NM_001363185.1; = p.G2787C on NM_052900.3) | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3456T>A p.N1152K (on ENST00000297405 / NM_001363185.1; = p.N1048K on NM_052900.3) | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP4F2 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- DCAF12L1 | c.184G>T p.G62W | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DDX4 | c.1895G>T p.G632V | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDX60L | c.3292G>A p.V1098I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- DNAH7 | c.11540T>A p.L3847H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH9 | c.13187C>A p.A4396D | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- DNAJC6 | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DNMBP | c.4091A>T p.E1364V | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DPP3 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2
- DPY19L2 | c.927G>T p.Q309H | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DYSF | c.3295G>T p.E1099* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- E2F7 | c.2731G>T p.D911Y | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.731); called by muse, mutect2
- EEA1 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 33/346 reads (10%) | called by muse, mutect2
- ELAPOR2 | c.2359G>T p.G787* (on ENST00000450689 / NM_001142749.3; = p.G620* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- EXOSC9 | c.348A>G p.I116M | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2
- EXTL1 | c.1603C>A p.H535N | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- FBN2 | c.1169G>T p.C390F | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXO40 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 18/271 reads (7%) | called by muse, mutect2
- FNTB | c.725T>A p.V242E | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- FOXP2 | c.1819G>T p.A607S | Missense Mutation (SNP) | VAF 91/504 reads (18%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FPGT | c.1708A>C p.N570H | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); called by muse, mutect2
- FRAS1 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.592); called by muse, mutect2
- FREM1 | c.4348G>T p.V1450F | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- FSIP2 | c.3434C>A p.P1145H | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GABRB1 | c.138del p.G47Dfs*26 | Frame Shift Del (DEL) | VAF 34/378 reads (9%) | called by mutect2, pindel
- GAK | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GFRAL | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- GHRH | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 34/586 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.107); called by muse, mutect2
- GIMD1 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.397); called by muse, mutect2
- GPR26 | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- GRID1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAPLN3 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- HDAC7 | c.2314C>A p.P772T (on ENST00000427332; = p.P811T on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.108); called by muse, mutect2
- HIVEP1 | c.1036A>T p.T346S | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HSD11B1 | c.818G>T p.R273M | Missense Mutation (SNP) | VAF 30/316 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); called by muse, mutect2
- IGKV3-20 | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 68/814 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); called by muse, mutect2
- IL17F | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2
- INPP4B | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- ITGA8 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- ITGAL | c.126del p.R43Gfs*43 | Frame Shift Del (DEL) | VAF 14/134 reads (10%) | called by mutect2, pindel
- KCNE2 | c.308T>A p.L103Q | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- KCNJ3 | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KCNQ2 | c.2126C>T p.P709L (on ENST00000359125 / NM_172107.4; = p.P681L on NM_004518.6) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- KCTD7 | c.432G>T p.M144I | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.018); called by muse, mutect2
- KIAA1614 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1671 | c.2726A>T p.Q909L | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KIF21B | c.4501C>A p.P1501T (on ENST00000422435 / NM_001252100.2; = p.P1488T on NM_017596.4) | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KLHL1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 51/379 reads (13%) | called by muse, mutect2, varscan2
- KLK3 | c.335G>C p.R112T | Missense Mutation (SNP) | VAF 31/220 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- L3MBTL1 | c.316G>T p.E106* (on ENST00000418998 / NM_001377303.1; = p.E84* on NM_032107.5) | Nonsense Mutation (SNP) | VAF 33/318 reads (10%) | called by muse, mutect2, varscan2
- LAMB4 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LARP4 | c.526G>T p.V176L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); called by muse, varscan2
- LEP | c.-26C>T | Splice Region (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- LIG3 | c.1544A>T p.Q515L | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LORICRIN | c.104del p.G35Afs*304 | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | called by mutect2, varscan2
- LRRC55 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.037); called by muse, mutect2
- LRRK2 | c.1410del p.F470Lfs*10 | Frame Shift Del (DEL) | VAF 26/236 reads (11%) | called by mutect2, pindel
- MAP3K1 | c.2740G>T p.G914* | Nonsense Mutation (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- MBTPS1 | c.131A>T p.K44M | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- MCPH1 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MDH2 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- MDM1 | c.60-1G>A p.X20_splice | Splice Site (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- MLLT3 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- MON1B | c.95G>T p.G32V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.023); called by muse, mutect2
- MPHOSPH6 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- MPPED1 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- MS4A14 | c.1620G>T p.W540C | Missense Mutation (SNP) | VAF 19/288 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2
- MUC16 | c.39163A>G p.S13055G | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- MUC2 | c.1438A>T p.T480S | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.14); called by muse, mutect2
- MXRA8 | c.1220T>A p.L407Q | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH11 | c.634-3del | Splice Region (DEL) | VAF 22/248 reads (9%) | called by pindel, varscan2
- MYO18B | c.46del p.E16Kfs*43 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- MYO18B | c.4081-1G>T p.X1361_splice | Splice Site (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- MYO1B | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | called by muse, mutect2
- NACAD | c.1333G>T p.V445L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDNF | c.787G>C p.G263R | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- NEK1 | c.2806del p.A936Qfs*28 | Frame Shift Del (DEL) | VAF 18/172 reads (10%) | called by mutect2, pindel, varscan2
- NELFB | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NFKBID | c.548G>T p.R183L (on ENST00000396901; = p.R335L on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.109); called by muse, mutect2
- NKX2-8 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NLRP10 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.486); called by muse, mutect2
- NOS1 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- NRAP | c.4175C>A p.P1392H (on ENST00000359988 / NM_001322945.2; = p.P1357H on NM_006175.4) | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NRXN3 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2
- NSD1 | c.1232A>G p.H411R | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- OR10G7 | c.249G>C p.L83F | Missense Mutation (SNP) | VAF 24/488 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.033); called by muse, mutect2
- OR10G9 | c.89T>A p.L30Q | Missense Mutation (SNP) | VAF 30/518 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR11H7 | c.421T>A p.C141S | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2
- OR13C8 | c.819A>T p.E273D | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- OR2T10 | c.855G>T p.L285F | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- OR4C15 | c.1099A>T p.N367Y (on ENST00000314644; = p.N313Y on NM_001001920.2) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- OR4D1 | c.250G>T p.D84Y | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- OR51C1P | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- OR52E4 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- OR5K1 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- OTOF | c.4631C>T p.S1544F (on ENST00000272371 / NM_194248.3; = p.S777F on NM_004802.4) | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OTOF | c.2527C>A p.Q843K (on ENST00000272371 / NM_194248.3; = p.Q96K on NM_004802.4) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2
- PADI4 | c.711C>G p.Y237* | Nonsense Mutation (SNP) | VAF 15/165 reads (9%) | called by muse, mutect2, varscan2
- PAPPA2 | c.4117T>C p.S1373P | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PCDHA4 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 19/314 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.034); called by muse, mutect2
- PCDHB12 | c.1421G>T p.S474I | Missense Mutation (SNP) | VAF 42/650 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- PCDHB4 | c.1201A>T p.T401S | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- PEX5L | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- PHEX | c.1964G>T p.R655M | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PHGDH | c.1254_1255insT p.G419Wfs*56 | Frame Shift Ins (INS) | VAF 31/290 reads (11%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.3476G>A p.G1159E | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PLAG1 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PLCL1 | c.3278G>T p.G1093V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.217); called by muse, mutect2
- PLXNA4 | c.2189C>A p.P730H | Missense Mutation (SNP) | VAF 49/325 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNPLA6 | c.898G>T p.A300S (on ENST00000414982 / NM_001166111.2; = p.A252S on NM_006702.5) | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- POLG2 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POU2AF1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.405); called by muse, mutect2
- PRB2 | c.800C>A p.P267H | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.716); called by muse, varscan2
- PRR22 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- PRSS58 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PSAPL1 | c.662C>G p.A221G | Missense Mutation (SNP) | VAF 20/315 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- PTCD1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 43/618 reads (7%) | called by muse, mutect2
- PTCH2 | c.2492A>T p.Q831L | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RABGGTA | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RCAN1 | c.160T>A p.C54S | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- RECQL4 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- RIOX2 | c.646A>T p.R216W | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- RNF10 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2
- RP1 | c.2293G>A p.G765S | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RPS19 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 48/560 reads (9%) | called by muse, mutect2
- RYR1 | c.10006A>T p.K3336* | Nonsense Mutation (SNP) | VAF 19/165 reads (12%) | called by muse, mutect2, varscan2
- SASS6 | c.278A>C p.Q93P | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); called by muse, mutect2
- SATB2 | c.1543-1G>T p.X515_splice | Splice Site (SNP) | VAF 38/319 reads (12%) | called by muse, mutect2, varscan2
- SEMA4F | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- SEMA5B | c.1469A>T p.Y490F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SEPTIN14 | c.-13C>A | Splice Region (SNP) | VAF 210/362 reads (58%) | called by muse, varscan2
- SERBP1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2
- SETBP1 | c.889A>C p.S297R | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2
- SGSM1 | c.816G>T p.E272D | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- SLC26A3 | c.972-1G>T p.X324_splice | Splice Site (SNP) | VAF 26/217 reads (12%) | called by muse, mutect2, varscan2
- SLC39A12 | c.1261A>T p.I421F | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SLC4A7 | c.3279G>T p.L1093F | Missense Mutation (SNP) | VAF 50/372 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC6A15 | c.538G>C p.D180H | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2
- SLC9A1 | c.1640A>C p.K547T | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SLITRK2 | c.2061T>A p.Y687* | Nonsense Mutation (SNP) | VAF 64/232 reads (28%) | called by muse, varscan2
- SMARCA2 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMYD1 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX4 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by muse, varscan2
- SOGA1 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- SOX17 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- SPATA16 | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 31/293 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA6 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | called by muse, mutect2
- ST3GAL6 | c.-183-1G>T | Splice Site (SNP) | VAF 20/218 reads (9%) | called by muse, mutect2
- STK40 | c.76G>T p.G26* | Nonsense Mutation (SNP) | VAF 28/328 reads (9%) | called by muse, mutect2
- TBX15 | c.1064G>C p.G355A (on ENST00000369429 / NM_001330677.2; = p.G249A on NM_152380.3) | Missense Mutation (SNP) | VAF 48/486 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); called by muse, mutect2
- TEX55 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 43/427 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2
- THSD7A | c.3240C>A p.N1080K | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TM6SF2 | c.551G>T p.W184L | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TMEM272 | c.461T>C p.V154A | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TMEM47 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, varscan2
- TMPRSS5 | c.1360G>T p.D454Y | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TNNI2 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2
- TNRC6B | c.1513G>C p.G505R | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNRC6B | c.1514G>T p.G505V | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRGV2 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 35/378 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.933); called by muse, mutect2
- TRIM24 | c.3143dup p.L1048Ffs*3 (on ENST00000343526 / NM_015905.3; = p.L1014Ffs*3 on NM_003852.4) | Frame Shift Ins (INS) | VAF 9/71 reads (13%) | called by mutect2, pindel
- TRIM51GP | c.1129C>G p.L377V | Missense Mutation (SNP) | VAF 38/402 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- TRPC6 | c.1198C>A p.Q400K | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.977); called by muse, mutect2
- TRPS1 | c.398C>A p.A133E (on ENST00000220888 / NM_001330599.2; = p.A146E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); called by muse, mutect2
- UNC5D | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2
- UNC80 | c.8900C>T p.T2967I | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USH2A | c.9055+1G>T p.X3019_splice | Splice Site (SNP) | VAF 36/476 reads (8%) | called by muse, mutect2
- USP17L7 | c.641C>A p.S214* | Nonsense Mutation (SNP) | VAF 49/1180 reads (4%) | called by muse, mutect2
- USP37 | c.2603A>T p.Y868F | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.828); called by muse, mutect2
- VGLL3 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- VN1R2 | c.837G>T p.W279C | Missense Mutation (SNP) | VAF 34/252 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- VPS41 | c.2368A>C p.I790L | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- VWA2 | c.1878G>T p.R626S | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.14); called by muse, mutect2
- WDFY4 | c.2485A>C p.M829L | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- WDFY4 | c.4873G>T p.D1625Y | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WDR64 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- WDR91 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- YARS1 | c.1498G>T p.E500* | Nonsense Mutation (SNP) | VAF 47/394 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3634T>A p.C1212S | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF212 | c.1273A>T p.S425C | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2
- ZNF223 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF467 | c.539G>C p.R180P | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF726 | c.1919+7C>A | Splice Region (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.1420A>T p.S474C | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- AADACL4 | c.762T>C p.C254= | Silent (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- ABCB5 | c.2760C>T p.S920= (on ENST00000404938 / NM_001163941.2; = p.S475= on NM_178559.6) | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs758731764; called by muse, mutect2, varscan2
- ADGRA2 | c.477C>G p.L159= | Silent (SNP) | VAF 22/245 reads (9%) | called by muse, mutect2
- AGBL3 | c.1959C>T p.H653= | Silent (SNP) | VAF 23/138 reads (17%) | called by muse, mutect2, varscan2
- ALDOB | c.169C>A p.R57= | Silent (SNP) | VAF 36/339 reads (11%) | catalogued as COSV100878950; called by muse, mutect2, varscan2
- AMHR2 | c.627C>T p.I209= | Silent (SNP) | VAF 16/229 reads (7%) | catalogued as COSV99143097, COSV99143203; called by muse, mutect2
- ARSH | c.375G>T p.R125= | Silent (SNP) | VAF 11/55 reads (20%) | called by muse, mutect2, varscan2
- ATP1A2 | c.2922C>T p.A974= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- BPIFB2 | c.957G>T p.R319= | Silent (SNP) | VAF 15/91 reads (16%) | called by muse, varscan2
- C10orf90 | c.609C>T p.S203= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- C12orf57 | c.36C>T p.S12= | Silent (SNP) | VAF 40/349 reads (11%) | catalogued as rs782750207; called by muse, mutect2, varscan2
- CAMTA1 | c.1029C>A p.V343= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
- CFAP54 | c.5898C>A p.T1966= | Silent (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- CLCA2 | c.1047G>T p.V349= | Silent (SNP) | VAF 32/347 reads (9%) | catalogued as COSV100991296; called by muse, mutect2
- CNKSR2 | c.2466G>T p.G822= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs200902796; called by muse, varscan2
- CNTNAP2 | c.399C>A p.I133= | Silent (SNP) | VAF 26/302 reads (9%) | catalogued as COSV100672052, COSV62258622; called by muse, mutect2
- COL26A1 | c.693G>A p.A231= (on ENST00000313669 / NM_001278563.3; = p.A229= on NM_133457.4) | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs776272496, COSV58123915; called by muse, mutect2, varscan2
- COL6A2 | c.2598C>A p.A866= | Silent (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2, varscan2
- CPED1 | c.870G>T p.S290= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs774206526, COSV60014767; called by muse, mutect2
- CSMD1 | c.2640T>C p.P880= (on ENST00000520002; = p.P879= on NM_033225.6) | Silent (SNP) | VAF 14/184 reads (8%) | catalogued as COSV100144234; called by muse, mutect2
- CTCFL | c.1092C>T p.H364= | Silent (SNP) | VAF 15/206 reads (7%) | catalogued as COSV54780392; called by muse, mutect2
- DES | c.1153C>T p.L385= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- DRD3 | c.996C>A p.A332= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, varscan2
- DYRK4 | c.78G>A p.E26= | Silent (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2, varscan2
- DZIP1L | c.1605G>C p.G535= | Silent (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- EPHA5 | c.1632A>T p.T544= | Silent (SNP) | VAF 34/300 reads (11%) | called by muse, mutect2, varscan2
- EPHA7 | c.2097G>T p.G699= | Silent (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- ERC1 | c.1827C>T p.T609= (on ENST00000360905 / NM_178040.4; = p.T581= on NM_178039.4) | Silent (SNP) | VAF 16/246 reads (7%) | catalogued as rs1566165005, COSV61697925; called by muse, mutect2
- FH | c.1479A>T p.T493= | Silent (SNP) | VAF 20/307 reads (7%) | called by muse, mutect2
- HECW1 | c.2010C>T p.C670= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1167796583, COSV101224365; called by muse, mutect2, varscan2
- HMGA2 | c.318C>A p.A106= | Silent (SNP) | VAF 52/610 reads (9%) | catalogued as rs778563109, COSV101328913; called by muse, mutect2
- INPP5D | c.213C>A p.V71= | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as rs376938749; called by muse, mutect2, varscan2
- INSC | c.30G>T p.A10= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV65411465; called by muse, mutect2
- ITGA1 | c.1578G>T p.V526= | Silent (SNP) | VAF 31/342 reads (9%) | called by muse, mutect2
- ITGA10 | c.2622C>T p.A874= | Silent (SNP) | VAF 34/334 reads (10%) | called by muse, mutect2, varscan2
- ITGA6 | c.1713G>T p.G571= (on ENST00000442250; = p.G532= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/304 reads (10%) | called by muse, mutect2
- KIAA2012 | c.57G>A p.Q19= | Silent (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- KIF5A | c.1377C>A p.T459= | Silent (SNP) | VAF 19/314 reads (6%) | called by muse, mutect2
- KRT23 | c.996C>A p.I332= | Silent (SNP) | VAF 68/486 reads (14%) | called by muse, mutect2, varscan2
- LAMB4 | c.1869C>T p.A623= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as rs1038690378; called by muse, mutect2, varscan2
- LRRC4C | c.1767T>A p.A589= | Silent (SNP) | VAF 34/432 reads (8%) | called by muse, mutect2
- MAPK9 | c.594G>T p.L198= | Silent (SNP) | VAF 10/163 reads (6%) | called by muse, mutect2
- MORC1 | c.1818T>C p.H606= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV51717861; called by muse, mutect2, varscan2
- MYCBP2 | c.4491A>G p.L1497= (on ENST00000357337; = p.L1535= on NM_015057.5) | Silent (SNP) | VAF 53/278 reads (19%) | called by muse, mutect2, varscan2
- MYH13 | c.4248A>G p.A1416= | Silent (SNP) | VAF 25/271 reads (9%) | catalogued as rs766090024; called by muse, mutect2
- MYH7 | c.3378C>T p.R1126= | Silent (SNP) | VAF 56/468 reads (12%) | called by muse, mutect2, varscan2
- MYOM2 | c.274C>T p.L92= | Silent (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2
- NAA30 | c.882G>A p.R294= | Silent (SNP) | VAF 33/307 reads (11%) | called by muse, mutect2, varscan2
- NUAK1 | c.1599G>T p.A533= | Silent (SNP) | VAF 50/472 reads (11%) | called by muse, mutect2, varscan2
- NUP214 | c.138C>T p.N46= | Silent (SNP) | VAF 21/319 reads (7%) | catalogued as rs1309589198; called by muse, mutect2
- NWD2 | c.51G>T p.A17= | Silent (SNP) | VAF 41/348 reads (12%) | catalogued as COSV58751743; called by muse, mutect2, varscan2
- PADI2 | c.694C>A p.R232= | Silent (SNP) | VAF 26/187 reads (14%) | catalogued as rs368362488; called by muse, mutect2, varscan2
- PADI2 | c.489C>T p.P163= | Silent (SNP) | VAF 20/164 reads (12%) | called by muse, varscan2
- PATE3 | c.18G>A p.L6= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- PCDH10 | c.1446C>A p.I482= | Silent (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2, varscan2
- PCDHB11 | c.2139G>C p.L713= | Silent (SNP) | VAF 25/394 reads (6%) | called by muse, mutect2
- PDE6B | c.174G>T p.A58= | Silent (SNP) | VAF 9/232 reads (4%) | called by muse, mutect2
- PDILT | c.1383A>T p.P461= | Silent (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2
- PHLDB2 | c.525G>T p.S175= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV101208401, COSV67312695; called by muse, mutect2, varscan2
- PLCG2 | c.2628G>T p.L876= | Silent (SNP) | VAF 20/203 reads (10%) | called by muse, mutect2
- POMK | c.798G>A p.V266= | Silent (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- PROM2 | c.2374C>T p.L792= | Silent (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- RNF165 | c.591C>A p.P197= | Silent (SNP) | VAF 24/199 reads (12%) | called by muse, mutect2, varscan2
- RP1L1 | c.4872G>T p.L1624= | Silent (SNP) | VAF 13/177 reads (7%) | catalogued as rs1439283032; called by muse, mutect2
- RPS11 | c.315C>T p.R105= | Silent (SNP) | VAF 41/376 reads (11%) | catalogued as COSV54525966; called by muse, mutect2, varscan2
- RUNX1T1 | c.36G>T p.L12= | Silent (SNP) | VAF 10/225 reads (4%) | called by muse, mutect2
- RYR2 | c.2265C>T p.I755= | Silent (SNP) | VAF 8/52 reads (15%) | called by mutect2, varscan2
- S100A4 | c.249C>T p.A83= | Silent (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- SEC16B | c.2466A>T p.T822= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs754540519; called by muse, mutect2
- SLC38A5 | c.1344C>A p.V448= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- SLC39A5 | c.1350C>G p.L450= | Silent (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- SLC7A3 | c.1110C>T p.F370= | Silent (SNP) | VAF 45/232 reads (19%) | called by muse, mutect2, varscan2
- STMN1 | c.174A>G p.E58= | Silent (SNP) | VAF 21/281 reads (7%) | catalogued as COSV100771316; called by muse, mutect2
- STRIP2 | c.1362A>C p.G454= | Silent (SNP) | VAF 15/237 reads (6%) | called by muse, mutect2
- SYT10 | c.1152C>G p.V384= | Silent (SNP) | VAF 18/270 reads (7%) | called by muse, mutect2
- TERT | c.837C>T p.A279= | Silent (SNP) | VAF 15/292 reads (5%) | catalogued as rs1448995569; called by muse, mutect2
- TRDN | c.129G>T p.T43= | Silent (SNP) | VAF 33/282 reads (12%) | called by muse, mutect2, varscan2
- USH2A | c.6282G>T p.G2094= | Silent (SNP) | VAF 22/334 reads (7%) | called by muse, mutect2
- VWCE | c.2502C>T p.F834= | Silent (SNP) | VAF 12/120 reads (10%) | called by muse, mutect2, varscan2
- XYLT1 | c.1620C>A p.P540= | Silent (SNP) | VAF 18/174 reads (10%) | catalogued as COSV99762098; called by muse, mutect2
- ZNF385D | c.1023A>C p.A341= | Silent (SNP) | VAF 28/380 reads (7%) | called by muse, mutect2
- ZNF771 | c.468C>T p.F156= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV100075167; called by muse, mutect2
- AC092718.9 | chr16:81147501 A>T | 5'Flank (SNP) | VAF 8/81 reads (10%) | called by muse, mutect2, varscan2
- AFDN | chr6:167976100 G>T | 3'Flank (SNP) | VAF 20/384 reads (5%) | called by muse, mutect2
- AKAP9 | c.11758+33C>T | Intron (SNP) | VAF 34/398 reads (9%) | called by muse, mutect2
- ALDH1A3 | chr15:100877857 G>T | 5'Flank (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- ANKRD26P1 | n.816G>C | RNA (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- AP000769.5 | chr11:65499538 G>T | 5'Flank (SNP) | VAF 22/164 reads (13%) | called by muse, mutect2, varscan2
- ARPC5 | c.*4107C>T | 3'UTR (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- BEND5 | c.-22G>T | 5'UTR (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- C11orf58 | c.-18G>T | 5'UTR (SNP) | VAF 19/182 reads (10%) | called by muse, mutect2, varscan2
- C16orf97 | n.318G>T | RNA (SNP) | VAF 18/216 reads (8%) | catalogued as rs922669290; called by muse, mutect2
- C1orf229 | n.357G>T | RNA (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- CCDC110 | c.10+50G>A | Intron (SNP) | VAF 10/192 reads (5%) | called by muse, mutect2
- CHRNA4 | c.*2918C>A | 3'UTR (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- CMTM3 | c.400-97T>C | Intron (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- CSN1S2AP | n.409C>T | RNA (SNP) | VAF 20/320 reads (6%) | called by muse, mutect2
- D2HGDH | c.1141-140G>T | Intron (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- DMAC2L | chr14:50332201 C>G | 3'Flank (SNP) | VAF 38/261 reads (15%) | catalogued as rs767410543, COSV99367231; called by muse, mutect2, varscan2
- DUSP22 | c.-85C>A | 5'UTR (SNP) | VAF 14/214 reads (7%) | catalogued as COSV60524862; called by muse, mutect2
- EIF3IP1 | n.159A>T | RNA (SNP) | VAF 30/188 reads (16%) | called by muse, mutect2, varscan2
- FAM205BP | n.82A>T | RNA (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- FBXO9 | c.1084-766G>T | Intron (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
- FGA | c.-16C>A | 5'UTR (SNP) | VAF 22/293 reads (8%) | called by muse, mutect2
- GCM1 | c.-12C>A | 5'UTR (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- GLYR1 | c.155+1429G>T | Intron (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- GSDMD | c.824-12C>T | Intron (SNP) | VAF 5/35 reads (14%) | called by mutect2, varscan2
- IFITM2 | c.*50A>T | 3'UTR (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- IGSF9B | c.3984-316A>G | Intron (SNP) | VAF 23/344 reads (7%) | called by muse, mutect2
- LINC00917 | n.1373A>T | RNA (SNP) | VAF 22/282 reads (8%) | called by muse, mutect2
- LINC00934 | n.1434+34C>T | Intron (SNP) | VAF 8/117 reads (7%) | catalogued as rs904585712; called by muse, mutect2
- LINC02272 | n.165G>A | RNA (SNP) | VAF 31/239 reads (13%) | catalogued as rs1270283466; called by muse, mutect2, varscan2
- LRATD1 | n.593G>T | RNA (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- MIR7-3 | chr19:4769612 G>T | 5'Flank (SNP) | VAF 13/126 reads (10%) | called by muse, mutect2
- NOTCH2 | c.2479+73G>C | Intron (SNP) | VAF 35/522 reads (7%) | called by muse, mutect2
- NRK | c.4354-855G>T | Intron (SNP) | VAF 56/190 reads (29%) | called by muse, mutect2, varscan2
- PCDH15 | c.3374-1868C>A | Intron (SNP) | VAF 8/133 reads (6%) | catalogued as COSV57369529; called by muse, mutect2
- PHF2 | c.*1677G>C | 3'UTR (SNP) | VAF 16/133 reads (12%) | called by muse, mutect2, varscan2
- PSMB3 | c.-7C>T | 5'UTR (SNP) | VAF 20/246 reads (8%) | called by muse, mutect2
- RABL3 | chr3:120742523 C>A | 5'Flank (SNP) | VAF 22/310 reads (7%) | catalogued as rs532472033, COSV99381943; called by muse, mutect2
- RAD51D | c.*508A>T | 3'UTR (SNP) | VAF 27/357 reads (8%) | called by muse, mutect2
- RANBP10 | c.1353-15A>C | Intron (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- RGS9 | c.1407+45G>T | Intron (SNP) | VAF 20/202 reads (10%) | catalogued as rs751755360; called by muse, mutect2
- ROBO2 | c.3935-1999G>T | Intron (SNP) | VAF 26/183 reads (14%) | called by muse, varscan2
- SHANK2 | c.1174+33063A>T | Intron (SNP) | VAF 54/582 reads (9%) | called by muse, mutect2
- SLC5A2 | c.1129+45C>A | Intron (SNP) | VAF 29/186 reads (16%) | called by muse, mutect2, varscan2
- SNORD115-14 | n.79C>A | RNA (SNP) | VAF 21/348 reads (6%) | catalogued as rs1179545215; called by muse, mutect2
- SPATA31C1 | n.3329C>A | RNA (SNP) | VAF 20/441 reads (5%) | called by muse, mutect2
- STMN4 | c.510+84C>A | Intron (SNP) | VAF 42/319 reads (13%) | called by muse, mutect2, varscan2
- TMED10 | c.412-3248C>T | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- TOX3 | c.*312A>G | 3'UTR (SNP) | VAF 13/95 reads (14%) | called by muse, mutect2, varscan2
- TPP1 | c.18-42G>T | Intron (SNP) | VAF 37/352 reads (11%) | called by muse, mutect2, varscan2
- TRPA1 | c.1811+47G>T | Intron (SNP) | VAF 31/419 reads (7%) | called by muse, mutect2
- UBE2DNL | n.313A>T | RNA (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2, varscan2
- VLDLR | c.-55G>C | 5'UTR (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- XIRP2 | c.*280T>A | 3'UTR (SNP) | VAF 14/126 reads (11%) | catalogued as COSV54680408; called by muse, varscan2
- XIST | n.10891G>A | RNA (SNP) | VAF 21/87 reads (24%) | called by muse, varscan2
- ZNF971P | n.1053C>A | RNA (SNP) | VAF 33/486 reads (7%) | called by muse, mutect2
